Gene-level copy-number profile of tumor specimen TCGA-85-A510-01A from TCGA case TCGA-85-A510, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 74.1 years (27,067 days).
Specimen TCGA-85-A510-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.2943c79f-766e-446e-ace1-6d4292ef7c31.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-A510-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e2c7c5f-f889-43bd-95e9-623709c9a2e9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 686; copy number 2: 26,599; copy number 3: 20,453; copy number 4: 3,563; copy number 5: 7,380; copy number 6: 113; copy number 7: 442; copy number 8: 292; copy number 10: 13; copy number 16: 71; copy number 17: 39; copy number 24: 24; copy number 28: 106; copy number 32: 39.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-A510-01A-11D-A26L-01): tumor purity 0.55, ploidy 2.7, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,492 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:171,248,471–180,123,890, 170 genes, copy number 5–8 (broad region; genes not listed).
- chr3:108,822,770–198,222,513, 1,612 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 7–8 (broad region; genes not listed).
- chr6:20,534,457–21,232,404, 1 gene, copy number 5 (within-gene range 4–5): CDKAL1.
- chr6:20,756,103–25,620,530, 68 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr8:2,935,353–4,994,972, 1 gene, copy number 5 (within-gene range 4–6): CSMD1.
- chr8:4,317,388–145,066,685, 2,420 genes, copy number 5–6 (broad region; genes not listed).
- chr14:32,074,946–32,272,301, 8 genes, copy number 10: ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1.
- chr14:32,373,337–32,484,800, 3 genes, copy number 10: AL136298.1, RN7SL660P, MTCO1P2.
- chr14:35,538,352–41,298,734, 80 genes, copy number 10–32 (within-gene range 4–32) (broad region; genes not listed).
- chr16:11,555–26,137,685, 897 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:79,707,176–83,095,122, 185 genes, copy number 5 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 5 (broad region; genes not listed).
- chr19:22,137,931–23,874,701, 83 genes, copy number 6 (within-gene range 3–6) (broad region; genes not listed).
- chr19:30,850,975–40,465,764, 420 genes, copy number 5–28 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 686. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
